Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5198, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5198-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA-BP-5198

Clinical Diagnosis & History:

Incidental right upper pole kidney mass approximately 7 cm in diameter involving renal sinus on imaging.

Specimens Submitted:

1: Kidney, right upper pole; partial nephrectomy

2: Lymph nodes, pericaval; biopsy

DIAGNOSIS:

1. Kidney, right upper pole; partial nephrectomy:

Tumor Type:

Renal cell carcinoma - ~~Conventional (clear cell) type~~

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 6.0 cm.

Local Invasion (for renal cortical types):

Involves renal sinus fat

Renal Vein Invasion:

Tumor invades multiple muscular branches of renal vein in the renal sinus

Surgical Margins:

Tumor present at renal parenchymal margin (for partial nephrectomy specimens only)

Non-Neoplastic Kidney:

Cortical scars, benign cortical cysts, and mild arteriosclerotic changes

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3b Tumor grossly extends into the renal vein(s) or vena cava below the diaphragm

2. Lymph nodes, pericaval; biopsy:

Lymph Nodes:

Not involved

Number of nodes examined:9

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and is labeled "right upper pole renal mass." It consists of a 6.5 x 6 x 5.5 cm wedge shaped portion of kidney with a suture marking the deep margin and a second suture marking the vascular margin. The vascular margin is grossly not involved by the tumor but a tumor embolus can be grossly identified in the lumen of the vessel. The parenchymal margin is inked black and the specimen is serially sectioned to reveal a 6.0 X 4.5 x 4.0 cm well circumscribed encapsulated tumor. The cut surfaces of the tumor are tan-yellow to orange and show focal hemorrhagic/necrotic areas. The clearance from the resection margin is 0.4 cm. A representative section of the nearest margin is submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS and the specimen is photographed.

Summary of sections:

T - tumor
PM - parenchymal margin
VM - vascular margin
VT - tumor embolus in the vessel
RS - representative sections
ADD - additional sections

2). The specimen is received in formalin, labeled "Paracaval lymph nodes" and consists of multiple pink tan firm possible lymph nodes ranging from 0.6 to 2.6 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph node

Summary of Sections:

Part 1: Kidney, right upper pole; partial nephrectomy

Block	Sect. Site	PCs
5	add	5
1	PM	1
1	RS	1
4	T	4
1	VM	1
1	VT	1

Part 2: Lymph nodes, pericaval; biopsy

Block	Sect. Site	PCs
1	BLN	2
3	LN	3

Source: NCI Genomic Data Commons file 60741f8d-0543-4474-b9dd-b3cd942c87cc (TCGA-BP-5198.C469FD3E-1E20-4BEE-8E22-BE77E5DA1EEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).